Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CZ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CZ-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: R frontal

Diagnosis: Oligoastrocytoma (grade II WHO)

Name of Pathologist:

ICD O-3
Oligoastrocytoma NOS 9382/3
Site CCF
Brain, Supratentorial NOS C71.0
path
Ⓟ Brain, frontal lobe C71.1
JAS 5/16/13

Un-/Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file ea0180d6-5685-407d-a860-1d2ecbd864b4 (TCGA-QH-A6CZ.B346A105-9790-4B51-B83E-7272FF381FA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).